Somatic mutation profile of tumor specimen TCGA-D6-A6EP-01A (aliquot TCGA-D6-A6EP-01A-11D-A31L-08) from TCGA case TCGA-D6-A6EP, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.1 years (22,674 days).
Specimen TCGA-D6-A6EP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 294a1ef5-a88c-4360-a0db-504d01ead70f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-A6EP-10A (Blood Derived Normal), aliquot TCGA-D6-A6EP-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fda6b406-7a81-4dcf-af76-223ed1fb15ff

The open-access MAF lists 127 somatic variants for this specimen: 97 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 28, Nonsense Mutation 7, 3'Flank 1, Splice Site 1, 5'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1BG | c.316A>T p.K106* | Nonsense Mutation (SNP) | VAF 94/147 reads (64%) | catalogued as COSV99568083; called by muse, mutect2, varscan2
- ABCA12 | c.87G>C p.L29F | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV55948101, COSV55951514, COSV99787804; called by muse, mutect2, varscan2
- AJUBA | c.1240-1G>T p.X414_splice | Splice Site (SNP) | VAF 14/49 reads (29%) | catalogued as COSV52984762, COSV99401134; called by muse, varscan2
- AKAP17A | c.1487C>G p.P496R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.63); catalogued as rs759580702, COSV100001776; called by muse, mutect2, varscan2
- ANKRD12 | c.3167C>T p.S1056L | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1475627148, COSV100040533; called by muse, mutect2, varscan2
- AOC1 | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV100710546; called by muse, mutect2, varscan2
- ATRNL1 | c.3820A>T p.M1274L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV100368974; called by muse, mutect2, varscan2
- AUTS2 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100714697; called by muse, mutect2, varscan2
- BEND2 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 59/64 reads (92%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV101191700; called by muse, mutect2, varscan2
- BMP6 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99306186; called by muse, mutect2, varscan2
- BMP6 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99306187; called by mutect2, varscan2
- BSCL2 | c.611G>C p.S204T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.181); catalogued as COSV99627807; called by muse, mutect2, varscan2
- BTLA | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.038); catalogued as COSV100569584; called by muse, mutect2, varscan2
- C9 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV99661554; called by muse, mutect2
- CARD11 | c.2245C>A p.L749M | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100829064, COSV100829185; called by muse, mutect2, varscan2
- CCDC73 | c.2703C>A p.Y901* | Nonsense Mutation (SNP) | VAF 86/97 reads (89%) | catalogued as COSV100066195; called by muse, mutect2, varscan2
- CD207 | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as COSV101338518; called by muse, mutect2, varscan2
- CDH7 | c.1414A>T p.I472L | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV100541206; called by muse, mutect2, varscan2
- CENPJ | c.3607G>C p.D1203H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55034119; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1047T>G p.I349M | Missense Mutation (SNP) | VAF 81/91 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.242); catalogued as COSV100291753; called by muse, mutect2, varscan2
- CKAP5 | c.3955G>T p.V1319F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100370275, COSV56366909; called by muse, mutect2, varscan2
- CLOCK | c.1429A>G p.R477G | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV100011501; called by muse, mutect2, varscan2
- CNGB3 | c.2399C>T p.T800I | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100181019; called by muse, mutect2, varscan2
- COL9A3 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs371562453; called by muse, mutect2, varscan2
- COPE | c.696G>A p.W232* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99447045; called by muse, mutect2, varscan2
- CRB1 | c.1564C>A p.L522I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100957609; called by muse, mutect2, varscan2
- CX3CL1 | c.560G>C p.R187P | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV99136234; called by muse, mutect2, varscan2
- DEF8 | c.1487G>A p.S496N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99240132; called by muse, mutect2, varscan2
- DMTN | c.1182G>T p.K394N | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99741321; called by muse, mutect2, varscan2
- DOCK2 | c.5197A>T p.T1733S | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.97); catalogued as COSV99909645; called by muse, mutect2, varscan2
- EIF5 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV99384627; called by muse, mutect2, varscan2
- EYA1 | c.28C>A p.H10N | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.287); catalogued as COSV100378312, COSV58161832; called by muse, mutect2, varscan2
- FAM76B | c.127T>A p.C43S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100334541; called by muse, mutect2, varscan2
- GABBR2 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 59/66 reads (89%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV52315011, COSV99408906; called by muse, mutect2, varscan2
- GHR | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100049601; called by muse, mutect2, varscan2
- GPHB5 | c.41T>A p.L14H | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100030133, COSV58485736; called by muse, mutect2, varscan2
- HEATR5A | c.3896T>C p.V1299A | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs1230690565, COSV101119482; called by muse, mutect2, varscan2
- HNRNPF | c.811A>T p.M271L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV100562924; called by muse, mutect2, varscan2
- IDI2 | c.572T>A p.V191D | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV99479087; called by muse, mutect2, varscan2
- IKZF2 | c.755A>T p.D252V | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100563078; called by muse, mutect2, varscan2
- ITIH5 | c.1337T>A p.L446Q | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99903413; called by muse, mutect2, varscan2
- KDM6B | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 231/246 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99640586; called by muse, mutect2, varscan2
- KPRP | c.731C>A p.T244N | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.323); catalogued as COSV100908650; called by muse, mutect2, varscan2
- LRRC8E | c.927C>A p.F309L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.997); catalogued as COSV100142553; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV101010794; called by muse, mutect2, varscan2
- MAP3K19 | c.3683A>G p.H1228R | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV100207896; called by muse, mutect2, varscan2
- MCHR1 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 84/121 reads (69%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.899); catalogued as rs149149384; called by muse, mutect2, varscan2
- MMS19 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as COSV100512626; called by muse, mutect2, varscan2
- MTCL1 | c.4210G>C p.E1404Q (on ENST00000306329 / NM_001378206.1; = p.E1085Q on NM_015210.4) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV100093129, COSV60410727; called by muse, mutect2, varscan2
- MYH2 | c.4552C>A p.L1518I | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV99819055; called by muse, mutect2, varscan2
- NELFB | c.444C>G p.S148R | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100546753; called by muse, mutect2, varscan2
- NEO1 | c.2718G>A p.K906= | Splice Region (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99981106; called by muse, mutect2, varscan2
- NLRP7 | c.182C>G p.T61S | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.269); catalogued as COSV100051438; called by muse, mutect2, varscan2
- NPC1L1 | c.1354C>G p.R452G | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV99202555; called by muse, mutect2, varscan2
- NRF1 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV99781381; called by muse, mutect2, varscan2
- NRG3 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.443); catalogued as rs142991883, COSV100930362, COSV64557266; called by muse, mutect2, varscan2
- OCA2 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as COSV62356151; called by muse, mutect2, varscan2
- OR2B6 | c.446G>C p.W149S | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55128812, COSV99773515; called by muse, mutect2, varscan2
- OR52B6 | c.728C>A p.A243E | Missense Mutation (SNP) | VAF 92/105 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV61448418; called by muse, mutect2, varscan2
- OR56B4 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT tolerated (0.63); PolyPhen benign (0.192); catalogued as COSV100337617; called by muse, mutect2, varscan2
- PAK5 | c.1414G>C p.G472R | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100780981, COSV62038422; called by muse, mutect2, varscan2
- PEX5L | c.808A>T p.K270* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99827702; called by muse, mutect2, varscan2
- PLD1 | c.1720G>C p.A574P | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100577476; called by muse, mutect2, varscan2
- PLEKHG1 | c.1979T>A p.V660D | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100651414; called by muse, mutect2, varscan2
- PLPP4 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as rs375764875; called by muse, mutect2, varscan2
- PPP1R9A | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99194501; called by muse, mutect2, varscan2
- PPP2R2D | c.1339A>G p.I447V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.113); catalogued as rs782375706, COSV101409014; called by muse, mutect2, varscan2
- PPP6R3 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 38/56 reads (68%) | catalogued as COSV55734939, COSV99676060; called by muse, mutect2, varscan2
- PSAT1 | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 60/67 reads (90%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1352612318, COSV100716462; called by muse, mutect2, varscan2
- PTGIS | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 115/262 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99720574; called by muse, mutect2, varscan2
- PTPRD | c.2281G>A p.G761S | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as rs774424685, COSV100642598, COSV61932931; called by muse, mutect2, varscan2
- RET | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.071); catalogued as COSV100392010; called by muse, mutect2, varscan2
- RTN1 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV50720778; called by muse, mutect2, varscan2
- SEMA4G | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202147105; called by muse, mutect2, varscan2
- SMIM29 | c.142G>A p.E48K (on ENST00000394990 / NM_001008704.3; = p.E68K on NM_178508.5) | Missense Mutation (SNP) | VAF 107/227 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs770452095, COSV100102746; called by muse, mutect2, varscan2
- SPAG17 | c.1429G>C p.D477H | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.798); catalogued as COSV100307527; called by muse, mutect2, varscan2
- SPSB1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as COSV100049128; called by muse, mutect2, varscan2
- SPTB | c.2364C>G p.F788L | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV101071881; called by muse, mutect2, varscan2
- SUCO | c.1722G>C p.E574D | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99741778; called by muse, mutect2, varscan2
- SYNE1 | c.17581A>G p.T5861A (on ENST00000367255 / NM_182961.4; = p.T5790A on NM_033071.3) | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99550281; called by muse, mutect2, varscan2
- TBCD | c.1453C>G p.P485A | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV100832408; called by muse, mutect2, varscan2
- TENM1 | c.1643A>C p.H548P | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100948807; called by muse, mutect2, varscan2
- TNKS2 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65415082; called by muse, mutect2, varscan2
- TP53 | c.383del p.P128Lfs*42 | Frame Shift Del (DEL) | VAF 55/79 reads (70%) | catalogued as COSV53283607; called by mutect2, pindel, varscan2
- TRIM47 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs762817750, COSV99638276; called by muse, mutect2, varscan2
- TRIP12 | c.798C>G p.F266L | Missense Mutation (SNP) | VAF 41/43 reads (95%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.878); catalogued as COSV99389044, COSV99390823; called by muse, mutect2, varscan2
- TSPAN2 | c.618C>G p.F206L | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.903); catalogued as COSV101049770; called by muse, mutect2, varscan2
- TXNL4B | c.283G>T p.G95* | Nonsense Mutation (SNP) | VAF 56/89 reads (63%) | catalogued as COSV99194175; called by muse, mutect2, varscan2
- VEZF1 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 61/68 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99365544; called by muse, mutect2, varscan2
- VWA3A | c.2614A>C p.K872Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100240482; called by muse, mutect2
- WDR3 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV100307524; called by muse, mutect2, varscan2
- WDR7 | c.1690C>G p.Q564E | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.49); PolyPhen benign (0.197); catalogued as COSV99588213; called by muse, mutect2, varscan2
- WDR88 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 76/110 reads (69%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs575618079, COSV63452886; called by muse, mutect2, varscan2
- YAP1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1336676669, COSV56775349; called by muse, mutect2, varscan2
- ZIC4 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101267780; called by muse, mutect2, varscan2
- ZNF292 | c.5017G>A p.V1673I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100369599; called by muse, mutect2
- ZNF671 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100234801; called by muse, mutect2, varscan2
- ABCA7 | c.2532G>T p.G844= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs763479085, COSV99564906; called by muse, mutect2, varscan2
- ABCB6 | c.397C>A p.R133= | Silent (SNP) | VAF 76/138 reads (55%) | catalogued as COSV99521393; called by muse, mutect2, varscan2
- AK3 | c.459G>C p.L153= | Silent (SNP) | VAF 22/29 reads (76%) | catalogued as COSV100729368, COSV100729481; called by muse, mutect2, varscan2
- ANKRD11 | c.3384C>T p.D1128= | Silent (SNP) | VAF 140/193 reads (73%) | catalogued as COSV99968033; called by muse, mutect2, varscan2
- ARHGAP15 | c.960C>A p.G320= | Silent (SNP) | VAF 64/71 reads (90%) | catalogued as COSV54517494; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1587G>T p.V529= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100863561; called by muse, mutect2, varscan2
- C9 | c.54C>A p.I18= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99661559; called by muse, mutect2
- CELSR1 | c.7314G>T p.R2438= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99416402; called by muse, mutect2, varscan2
- COL28A1 | c.2391A>G p.L797= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV101258257; called by muse, mutect2
- CYP4F12 | c.498C>A p.I166= | Silent (SNP) | VAF 43/69 reads (62%) | catalogued as COSV100215543, COSV100215899, COSV61173671; called by muse, mutect2, varscan2
- DMD | c.498C>T p.G166= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV55903149; called by muse, mutect2, varscan2
- FOXA1 | c.1341G>A p.R447= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as rs867072933, COSV99163174; called by muse, mutect2, varscan2
- IFI44 | c.1050C>T p.S350= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV100877246; called by muse, mutect2, varscan2
- MAVS | c.1278C>A p.S426= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1244992992, COSV100816213; called by muse, mutect2, varscan2
- NFS1 | c.1122C>A p.A374= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as COSV100931826; called by muse, mutect2, varscan2
- NHEJ1 | c.738G>T p.L246= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100591774; called by muse, mutect2, varscan2
- PAK2 | c.1140A>T p.G380= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV100505756; called by muse, mutect2, varscan2
- PHF2 | c.1140A>C p.A380= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV100822966; called by muse, mutect2, varscan2
- PRR19 | c.1070G>A p.*357= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100003557; called by muse, mutect2, varscan2
- RBM12B | c.1548A>G p.P516= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as COSV101234455; called by muse, mutect2, varscan2
- SAMD14 | c.69G>A p.T23= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs145637965, COSV99557314; called by muse, mutect2, varscan2
- SLC30A4 | c.1077T>C p.D359= | Silent (SNP) | VAF 46/117 reads (39%) | catalogued as COSV99970075; called by muse, mutect2, varscan2
- SORBS1 | c.2775G>T p.V925= (on ENST00000361941 / NM_001034954.2; = p.V575= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/84 reads (61%) | catalogued as COSV99527223; called by muse, mutect2, varscan2
- SYT6 | c.1440C>T p.N480= (on ENST00000610222 / NM_001366225.1; = p.N395= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/99 reads (55%) | catalogued as rs556527664, COSV101059600, COSV65773774; called by muse, mutect2, varscan2
- TNNT2 | c.390C>T p.L130= | Silent (SNP) | VAF 26/172 reads (15%) | catalogued as rs758543857, COSV52661465; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTC6 | c.310C>T p.L104= (on ENST00000267368; = p.L1373= on NM_001310135.3) | Silent (SNP) | VAF 77/133 reads (58%) | catalogued as rs1269224137, COSV99941445; called by muse, mutect2, varscan2
- ZCCHC14 | c.24C>T p.F8= (on ENST00000268616; = p.F145= on NM_015144.3) | Silent (SNP) | VAF 36/56 reads (64%) | catalogued as rs1293778820, COSV99233272; called by muse, mutect2, varscan2
- ZP1 | c.1230G>A p.R410= | Silent (SNP) | VAF 27/202 reads (13%) | catalogued as rs778999173, COSV99612101; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445748 G>T | 3'Flank (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- SPTSSA | c.-2G>A | 5'UTR (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99987703; called by muse, mutect2
